Somatic mutation profile of tumor specimen TCGA-2Z-A9JQ-01A (aliquot TCGA-2Z-A9JQ-01A-11D-A42J-10) from TCGA case TCGA-2Z-A9JQ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 66.4 years (24,244 days).
Specimen TCGA-2Z-A9JQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea48d09f-64f8-4d5e-975d-1107e5943ba3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2Z-A9JQ-10A (Blood Derived Normal), aliquot TCGA-2Z-A9JQ-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/900ac103-6b86-459e-819f-2ebd89d025c0

The open-access MAF lists 90 somatic variants for this specimen: 65 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 23, Frame Shift Del 12, Nonsense Mutation 5, In Frame Del 2, Splice Region 1, Splice Site 1, 5'UTR 1, Frame Shift Ins 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD17 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.825); catalogued as COSV100429662, COSV58227546; called by muse, mutect2, varscan2
- ANKRD2 | c.985C>T p.H329Y | Missense Mutation (SNP) | VAF 84/208 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as rs1327193283, COSV100080985; called by muse, mutect2, varscan2
- ATP10D | c.3315G>T p.W1105C | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs749242976, COSV99905911; called by muse, mutect2, varscan2
- BICRA | c.4084A>G p.T1362A | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.73); catalogued as COSV101194403; called by muse, mutect2, varscan2
- CACNA1D | c.855T>G p.Y285* | Nonsense Mutation (SNP) | VAF 32/88 reads (36%) | catalogued as COSV99859155; called by muse, mutect2, varscan2
- CDH4 | c.2262G>A p.M754I | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs780814504, COSV100849318; called by muse, mutect2, varscan2
- COL28A1 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 104/231 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.165); catalogued as COSV101258809; called by muse, mutect2, varscan2
- CUL3 | c.631G>T p.E211* | Nonsense Mutation (SNP) | VAF 51/141 reads (36%) | catalogued as COSV100023589; called by muse, mutect2, varscan2
- DHX35 | c.1703A>G p.H568R | Missense Mutation (SNP) | VAF 35/85 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV99327091; called by muse, mutect2, varscan2
- DSCAM | c.851G>T p.R284L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.23); catalogued as COSV101260970, COSV68033499; called by muse, mutect2, varscan2
- FANCA | c.3731A>T p.K1244M | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.135); catalogued as COSV99235163; called by muse, mutect2, varscan2
- FDXR | c.1384G>A p.D462N (on ENST00000293195 / NM_024417.5; = p.D468N on NM_004110.6) | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.845); catalogued as COSV99501234; called by muse, mutect2, varscan2
- FRAS1 | c.7211C>T p.S2404F | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV99354247; called by muse, mutect2, varscan2
- HERC1 | c.13138G>C p.D4380H | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.12); catalogued as COSV101496743; called by muse, mutect2
- ILF2 | c.680T>C p.L227P | Missense Mutation (SNP) | VAF 64/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100721976; called by muse, mutect2, varscan2
- IRF4 | c.811C>T p.P271S | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.728); catalogued as COSV101110918; called by muse, mutect2, varscan2
- KRT6A | c.1318G>C p.D440H | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV58104582; called by muse, mutect2, varscan2
- KRT72 | c.943G>T p.E315* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV99537398; called by muse, mutect2, varscan2
- LOX | c.332G>C p.G111A | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV99140662; called by muse, mutect2, varscan2
- MAP1A | c.4782G>T p.K1594N | Missense Mutation (SNP) | VAF 58/134 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.429); catalogued as COSV100288974; called by muse, mutect2, varscan2
- MAP3K19 | c.116T>A p.L39* | Nonsense Mutation (SNP) | VAF 23/59 reads (39%) | catalogued as COSV100208935; called by muse, mutect2, varscan2
- MAP4K2 | c.2188G>A p.G730S | Missense Mutation (SNP) | VAF 30/60 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99581351; called by muse, mutect2, varscan2
- MDN1 | c.4106T>A p.M1369K | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV101021597; called by muse, mutect2, varscan2
- MUC17 | c.5891G>T p.S1964I | Missense Mutation (SNP) | VAF 52/112 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.093); catalogued as COSV100074336; called by muse, mutect2, varscan2
- NOTCH2 | c.5098G>T p.A1700S | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.194); catalogued as COSV99865587; called by muse, mutect2, varscan2
- NOTCH2 | c.5097G>A p.M1699I | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99865590; called by muse, mutect2, varscan2
- NRAP | c.1261G>A p.E421K (on ENST00000359988 / NM_001322945.2; = p.E386K on NM_006175.4) | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.89); PolyPhen benign (0.097); catalogued as COSV100748526, COSV63488802; called by muse, mutect2, varscan2
- OBP2B | c.301C>G p.L101V | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0.012); catalogued as COSV100922901; called by muse, mutect2, varscan2
- PATJ | c.1706G>C p.R569T | Missense Mutation (SNP) | VAF 49/88 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100334605, COSV57156017; called by muse, mutect2, varscan2
- PCDHA2 | c.1794C>G p.D598E | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100974053, COSV65366677; called by muse, mutect2, varscan2
- PEAR1 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as COSV52772338, COSV52772361; called by muse, mutect2, varscan2
- PLCB2 | c.272A>G p.D91G | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as COSV99542357; called by muse, mutect2, varscan2
- PPARGC1B | c.718C>T p.P240S | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.996); catalogued as rs761739239, COSV100494954; called by muse, mutect2, varscan2
- PRDM10 | c.1646T>C p.L549S | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV100456901; called by muse, mutect2, varscan2
- PSMB1 | c.73C>A p.P25T | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.282); catalogued as COSV51530629, COSV51530762; called by mutect2, varscan2
- QARS1 | c.1667G>T p.C556F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.43); PolyPhen probably damaging (1); catalogued as COSV100070188; called by muse, mutect2, varscan2
- RGPD2 | c.4239A>T p.K1413N | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.96); catalogued as COSV100553075; called by mutect2, varscan2
- SFTPD | c.367del p.L123Wfs*7 | Frame Shift Del (DEL) | VAF 19/50 reads (38%) | catalogued as rs1448137620, COSV64853250, COSV64853732; called by mutect2, pindel, varscan2
- SLC37A4 | c.610T>C p.S204P | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.093); catalogued as COSV100421575; called by muse, mutect2
- SLC45A2 | c.107T>C p.I36T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV99672938; called by muse, mutect2, varscan2
- SOCS5 | c.1106T>C p.L369P | Missense Mutation (SNP) | VAF 63/128 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100125382; called by muse, mutect2, varscan2
- TACC3 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as COSV100508857; called by muse, mutect2, varscan2
- TACC3 | c.356A>T p.Q119L | Missense Mutation (SNP) | VAF 58/111 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV100508860; called by muse, mutect2, varscan2
- TERT | c.3010A>G p.I1004V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as COSV99719586; called by muse, mutect2, varscan2
- TERT | c.3009G>C p.K1003N | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); catalogued as COSV99719588; called by muse, mutect2, varscan2
- USH2A | c.2777G>A p.R926H | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.12); catalogued as rs146916397; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- VWA3B | c.2148C>T p.S716= | Splice Region (SNP) | VAF 13/39 reads (33%) | catalogued as COSV101346099; called by muse, mutect2, varscan2
- ZFP36L2 | c.505A>G p.K169E | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV99144020; called by muse, mutect2, varscan2
- ZNF343 | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.54); PolyPhen benign (0.222); catalogued as COSV99601539; called by muse, mutect2, varscan2
- ZNF479 | c.381del p.K127Nfs*74 | Frame Shift Del (DEL) | VAF 131/371 reads (35%) | catalogued as rs782331095; called by mutect2, pindel, varscan2
- ADGRA1 | c.375del p.P126Rfs*171 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- ALOX12B | c.2037dup p.N680Qfs*17 | Frame Shift Ins (INS) | VAF 87/174 reads (50%) | called by mutect2, pindel, varscan2
- CBLL1 | c.42_47delinsCAT p.G15_S16delinsI | In Frame Del (DEL) | VAF 111/294 reads (38%) | called by pindel, varscan2*
- CNTN5 | c.117_118insTTGAGTTGAGTTG p.S40Lfs*3 | Nonsense Mutation (INS) | VAF 21/97 reads (22%) | called by mutect2, pindel*, varscan2*
- ELANE | c.701del p.P234Rfs*6 | Frame Shift Del (DEL) | VAF 65/143 reads (45%) | called by mutect2, pindel, varscan2
- EPB41L4B | c.579-1G>A p.X193_splice | Splice Site (SNP) | VAF 20/321 reads (6%) | called by muse, mutect2
- FKBP10 | c.1034del p.P345Rfs*20 | Frame Shift Del (DEL) | VAF 23/89 reads (26%) | called by mutect2, pindel, varscan2
- FRAS1 | c.1588del p.A530Pfs*9 | Frame Shift Del (DEL) | VAF 38/116 reads (33%) | called by mutect2, pindel, varscan2
- GCC2 | c.3688_3689del p.K1230Gfs*11 | Frame Shift Del (DEL) | VAF 213/628 reads (34%) | called by mutect2, pindel, varscan2
- KDM6B | c.501del p.K168Rfs*30 | Frame Shift Del (DEL) | VAF 27/115 reads (23%) | called by mutect2, pindel, varscan2
- LONRF3 | c.427_439del p.A143Rfs*56 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | called by mutect2, pindel
- OAS3 | c.1344_1346del p.C449del | In Frame Del (DEL) | VAF 10/27 reads (37%) | called by mutect2, pindel, varscan2
- PLS1 | c.14del p.T5Ifs*19 | Frame Shift Del (DEL) | VAF 70/176 reads (40%) | called by mutect2, pindel*, varscan2
- PLXNB1 | c.3481del p.D1161Ifs*22 | Frame Shift Del (DEL) | VAF 33/116 reads (28%) | called by mutect2, pindel, varscan2
- TXNDC2 | c.254del p.E85Gfs*85 (on ENST00000306084 / NM_001098529.2; = p.E18Gfs*85 on NM_032243.6) | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | called by mutect2, pindel, varscan2
- APPL2 | c.1464T>C p.S488= | Silent (SNP) | VAF 30/70 reads (43%) | catalogued as COSV99314996; called by muse, mutect2, varscan2
- ARHGAP31 | c.2661C>T p.D887= | Silent (SNP) | VAF 48/107 reads (45%) | catalogued as COSV99957419; called by muse, mutect2, varscan2
- DCTN1 | c.1179G>A p.K393= | Silent (SNP) | VAF 20/37 reads (54%) | catalogued as COSV100721006; called by muse, mutect2, varscan2
- FAM122B | c.714C>T p.F238= (on ENST00000370790 / NM_001166599.3; = p.F239= on NM_145284.5) | Silent (SNP) | VAF 59/74 reads (80%) | catalogued as COSV99980446; called by muse, mutect2, varscan2
- HEATR9 | c.981C>A p.A327= | Silent (SNP) | VAF 23/121 reads (19%) | called by muse, mutect2, varscan2
- IBTK | c.3090T>A p.S1030= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV100091120; called by muse, mutect2, varscan2
- ILF2 | c.679C>T p.L227= | Silent (SNP) | VAF 66/188 reads (35%) | catalogued as COSV100721977; called by muse, mutect2, varscan2
- INAVA | c.459G>A p.A153= | Silent (SNP) | VAF 57/130 reads (44%) | catalogued as rs773964932, COSV66256004; called by muse, mutect2, varscan2
- IQCN | c.270C>T p.A90= | Silent (SNP) | VAF 42/90 reads (47%) | catalogued as COSV101148854, COSV66574267; called by muse, mutect2, varscan2
- KLHL36 | c.498C>T p.F166= | Silent (SNP) | VAF 32/61 reads (52%) | catalogued as COSV99256956; called by muse, mutect2, varscan2
- MDN1 | c.1548T>C p.D516= | Silent (SNP) | VAF 59/151 reads (39%) | catalogued as COSV101021598; called by muse, mutect2, varscan2
- MOSPD3 | c.144G>T p.R48= | Silent (SNP) | VAF 197/428 reads (46%) | catalogued as COSV99774997; called by muse, mutect2, varscan2
- MTPAP | c.927G>A p.R309= | Silent (SNP) | VAF 128/289 reads (44%) | catalogued as COSV53931696, COSV99554218; called by muse, mutect2, varscan2
- MTUS1 | c.3768A>T p.P1256= (on ENST00000262102 / NM_001363061.1; = p.P422= on NM_020749.4) | Silent (SNP) | VAF 42/99 reads (42%) | catalogued as COSV99286559; called by muse, mutect2, varscan2
- NUCB1 | c.33T>C p.L11= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV99618047; called by muse, mutect2, varscan2
- RTN2 | c.18G>T p.P6= | Silent (SNP) | VAF 59/140 reads (42%) | catalogued as rs760223103, COSV99839144; called by muse, mutect2, varscan2
- SCN11A | c.4188C>T p.S1396= | Silent (SNP) | VAF 33/82 reads (40%) | catalogued as COSV100182033; called by muse, mutect2, varscan2
- ST8SIA2 | c.580C>A p.R194= | Silent (SNP) | VAF 51/101 reads (50%) | catalogued as COSV99184483; called by muse, mutect2, varscan2
- STC1 | c.738T>C p.S246= | Silent (SNP) | VAF 30/55 reads (55%) | catalogued as COSV99282616; called by muse, mutect2, varscan2
- TIMP2 | c.147G>T p.A49= | Silent (SNP) | VAF 42/74 reads (57%) | catalogued as COSV99430694; called by muse, mutect2, varscan2
- TPTE | c.228A>G p.S76= (on ENST00000618007 / NM_199261.4; = p.S58= on NM_199259.4) | Silent (SNP) | VAF 139/564 reads (25%) | catalogued as rs369891740; called by muse, varscan2
- TTN | c.70830T>A p.V23610= (on ENST00000591111; = p.V16186= on NM_003319.4) | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV100621774; called by muse, mutect2, varscan2
- UNK | c.1932T>A p.A644= | Silent (SNP) | VAF 51/79 reads (65%) | catalogued as COSV99257158; called by muse, mutect2, varscan2
- LINC00482 | n.663del | RNA (DEL) | VAF 25/60 reads (42%) | called by mutect2, pindel, varscan2
- WDFY2 | c.-2C>T | 5'UTR (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99987288; called by muse, mutect2
